Somatic mutation profile of tumor specimen TCGA-VR-A8EZ-01A (aliquot TCGA-VR-A8EZ-01A-11D-A36J-09) from TCGA case TCGA-VR-A8EZ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 47.8 years (17,449 days).
Specimen TCGA-VR-A8EZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3f65052-e962-45f3-8f1b-64d33186c8f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VR-A8EZ-10A (Blood Derived Normal), aliquot TCGA-VR-A8EZ-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/210d0fda-e3fb-4bc2-b3a9-cfc65bc9df2b

The open-access MAF lists 156 somatic variants for this specimen: 121 protein-altering or splice-affecting, 31 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 31, Nonsense Mutation 10, Splice Site 3, Frame Shift Del 3, RNA 3, Splice Region 2, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHRNA1 | c.1072C>T p.R358W (on ENST00000261007 / NM_001039523.3; = p.R333W on NM_000079.4) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374391312, CM086805; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- SYNE1 | c.8695A>T p.R2899* (on ENST00000367255 / NM_182961.4; = p.R2906* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as rs119103243, CM070290; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 15/25 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs863224683, CM016206, COSV52686543, COSV52692226, COSV99368721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRE5 | c.1531G>A p.E511K (on ENST00000242786 / NM_078481.4; = p.E418K on NM_001784.5) | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.078); catalogued as rs748373111, COSV54391440; called by muse, mutect2, varscan2
- BARD1 | c.425C>A p.S142* | Nonsense Mutation (SNP) | VAF 31/41 reads (76%) | catalogued as COSV53609402; called by muse, mutect2, varscan2
- C6 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0.031); catalogued as COSV54720386; called by muse, mutect2, varscan2
- CDH10 | c.1875G>C p.L625= | Splice Region (SNP) | VAF 7/29 reads (24%) | catalogued as COSV52572288; called by muse, mutect2, varscan2
- CDH19 | c.1745G>T p.C582F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748560534; called by muse, mutect2, varscan2
- CDHR2 | c.2444G>T p.G815V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs1459492773; called by muse, mutect2, varscan2
- CHRM4 | c.538G>T p.V180L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV63126596, COSV63126736; called by muse, mutect2, varscan2
- CHRNA1 | c.880G>C p.V294L (on ENST00000261007 / NM_001039523.3; = p.V269L on NM_000079.4) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); catalogued as rs137852803, CM973279, COSV53681846; called by muse, mutect2, varscan2
- COL4A4 | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as rs762358388; called by muse, mutect2, varscan2
- CSPG4 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 119/242 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV57901585; called by muse, mutect2, varscan2
- DMBT1 | c.2411G>C p.G804A | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100352650, COSV100352669; called by muse, mutect2, varscan2
- ELFN2 | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762167710; called by muse, mutect2, varscan2
- ITGAD | c.1982C>G p.S661* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV66759688; called by muse, mutect2, varscan2
- KRT12 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV99288962; called by muse, mutect2, varscan2
- LONRF1 | c.1566+2T>C p.X522_splice | Splice Site (SNP) | VAF 14/42 reads (33%) | catalogued as COSV68036428; called by muse, mutect2, varscan2
- LRRC7 | c.665C>G p.A222G (on ENST00000651989 / NM_001370785.2; = p.A189G on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs755151095, COSV50543518, COSV99229145; called by muse, mutect2, varscan2
- OPA1 | c.3016G>A p.A1006T (on ENST00000361510 / NM_130837.3; = p.A951T on NM_015560.3) | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs1166323851; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR5L2 | c.199T>C p.S67P | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV101004218; called by muse, mutect2, varscan2
- RICTOR | c.545G>T p.R182I | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57127524; called by muse, mutect2, varscan2
- STAT1 | c.231C>A p.F77L | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated (0.19); PolyPhen benign (0.313); catalogued as COSV63115987; called by muse, mutect2, varscan2
- TRIM10 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.93); PolyPhen benign (0.011); catalogued as rs1235426930; called by muse, mutect2, varscan2
- TRIM36 | c.1891C>A p.Q631K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.855); catalogued as rs1389012210; called by muse, mutect2, varscan2
- UBQLN2 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1330837640; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- URGCP | c.223G>T p.E75* (on ENST00000453200 / NM_001077663.3; = p.E66* on NM_017920.4) | Nonsense Mutation (SNP) | VAF 13/81 reads (16%) | catalogued as COSV56253778; called by muse, mutect2, varscan2
- ABCA2 | c.1319G>A p.W440* (on ENST00000614293; = p.W410* on NM_001606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2, varscan2
- ADH1C | c.559G>T p.V187F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AK9 | c.485G>C p.R162T | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- AMY2B | c.226A>G p.R76G | Missense Mutation (SNP) | VAF 133/264 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APOB | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- BEGAIN | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- BLM | c.806G>C p.S269T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BNIP3L | c.567C>A p.F189L | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BRIP1 | c.995G>C p.C332S | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CACNA1A | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- CAMK1D | c.455A>C p.Y152S | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CARD6 | c.2198T>A p.L733H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- CCDC88A | c.4654C>T p.Q1552* (on ENST00000436346 / NM_001365480.1; = p.Q1524* on NM_018084.5) | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2
- CENPO | c.767-11_784del p.X256_splice | Splice Site (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel
- CEP192 | c.3428A>T p.K1143I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by mutect2, varscan2
- COL28A1 | c.1501G>T p.G501C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUL3 | c.1415G>A p.G472E | Missense Mutation (SNP) | VAF 39/53 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DALRD3 | c.1427C>T p.A476V (on ENST00000341949 / NM_001009996.3; = p.A309V on NM_018114.5) | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DOCK4 | c.2351C>G p.A784G | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- DOP1B | c.2413A>G p.T805A | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DYNC2I1 | c.2669G>T p.R890I | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EHMT1 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ENOX1 | c.63G>C p.M21I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- ENPP1 | c.479C>A p.T160N | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- FCRL5 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- FOXA3 | c.924C>G p.N308K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- FRMPD2 | c.967A>G p.T323A | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GABRG1 | c.308A>G p.D103G | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- GALNT3 | c.1048A>G p.R350G | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- GDF3 | c.1090G>T p.G364W | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- GLYATL2 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- GUSB | c.638G>C p.G213A | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HECA | c.1615G>A p.V539I | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HIPK1 | c.11A>T p.Q4L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- HMGCS2 | c.1062A>C p.K354N | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HSF5 | c.1017C>A p.F339L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- IBSP | c.169C>G p.R57G | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGDCC4 | c.908A>G p.Q303R | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- IGKV3D-7 | c.92C>A p.P31Q | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- INHBE | c.764A>T p.D255V | Missense Mutation (SNP) | VAF 65/74 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ITGA8 | c.673C>A p.Q225K | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KCNK2 | c.58G>A p.D20N (on ENST00000444842 / NM_001017425.3; = p.D5N on NM_014217.4) | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- LIN7C | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.079); called by muse, mutect2
- LRBA | c.5581G>C p.E1861Q | Missense Mutation (SNP) | VAF 50/68 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- LRP1B | c.7605C>G p.H2535Q | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2
- MED13 | c.3691G>A p.D1231N | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MIEF1 | c.1016T>C p.L339P | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- MOSPD2 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 19/30 reads (63%) | called by muse, mutect2, varscan2
- MPP5 | c.1706C>G p.S569C | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MRPL19 | c.739C>G p.L247V | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- MYH7B | c.1809G>T p.K603N | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYOM1 | c.4346A>T p.K1449M | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- N4BP2 | c.15G>T p.R5S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.381); called by muse, mutect2
- NCAPD2 | c.639C>A p.H213Q | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- NLRP9 | c.1216T>A p.Y406N | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOTCH1 | c.2018G>C p.S673T | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- OGDHL | c.2449A>T p.N817Y | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- OR10R2 | c.238T>C p.Y80H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5M3 | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- OSBPL6 | c.1756G>T p.V586F | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PAPPA | c.438dup p.I147Yfs*4 | Frame Shift Ins (INS) | VAF 19/33 reads (58%) | called by mutect2, pindel, varscan2
- PDE3A | c.3182C>T p.P1061L | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PIGN | c.1354G>T p.V452L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- PKN2 | c.2349G>C p.L783F | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- POMGNT2 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- POP1 | c.1582G>C p.E528Q | Missense Mutation (SNP) | VAF 5/111 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2
- PRDM1 | c.259C>A p.L87M | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRKCE | c.1718A>G p.Y573C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRPS2 | c.496A>G p.I166V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRRC2A | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTPRH | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- PTPRK | c.731A>T p.K244M | Missense Mutation (SNP) | VAF 78/169 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- RAB3C | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- RANBP2 | c.3779C>T p.S1260L | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RIMS4 | c.379A>C p.N127H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- RPL30 | c.285del p.I96Sfs*33 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- SCEL | c.1810A>G p.I604V (on ENST00000349847 / NM_144777.3; = p.I584V on NM_003843.4) | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SEMA5A | c.2113A>T p.K705* | Nonsense Mutation (SNP) | VAF 32/56 reads (57%) | called by muse, mutect2, varscan2
- SEPTIN4 | c.353C>G p.S118C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.246); called by muse, mutect2
- SLC10A7 | c.435+7A>G | Splice Region (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- SLC35A5 | c.109G>C p.V37L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SRPRA | c.211C>G p.Q71E | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- TEX15 | c.5074G>C p.E1692Q (on ENST00000256246; = p.E2075Q on NM_001350162.2) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNRC18 | c.8645G>T p.S2882I | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- TRMT5 | c.239G>T p.R80L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- TTN | c.86993_87008del p.L28998Hfs*9 (on ENST00000591111; = p.L21574Hfs*9 on NM_003319.4) | Frame Shift Del (DEL) | VAF 10/77 reads (13%) | called by mutect2, pindel, varscan2
- UBTF | c.474+1del p.X158_splice | Splice Site (DEL) | VAF 9/85 reads (11%) | called by mutect2, pindel, varscan2
- UNC5D | c.1581G>T p.M527I | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- VKORC1 | c.133G>C p.V45L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.148); called by muse, mutect2
- YARS2 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBED6CL | c.489_516del p.Q164Wfs*151 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel
- ZNF234 | c.1505A>T p.H502L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF556 | c.680G>C p.G227A | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZPBP2 | c.338A>G p.Y113C (on ENST00000348931 / NM_199321.3; = p.Y91C on NM_198844.3) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AGAP3 | c.2406G>C p.T802= (on ENST00000622464; = p.T838= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV101256905; called by muse, mutect2, varscan2
- ATG2A | c.5115C>G p.S1705= | Silent (SNP) | VAF 25/93 reads (27%) | called by muse, mutect2, varscan2
- CAVIN1 | c.840C>T p.R280= | Silent (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- CDC27 | c.2379A>G p.Q793= | Silent (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- CDH13 | c.330G>T p.V110= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV51845398; called by muse, varscan2
- CNTNAP3 | c.3099A>G p.R1033= | Silent (SNP) | VAF 60/911 reads (7%) | catalogued as rs753547642; called by muse, mutect2
- CPSF1 | c.519C>T p.H173= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs782746758, COSV100574697; called by muse, mutect2, varscan2
- CRYBG1 | c.2319G>A p.E773= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs912544614; called by muse, mutect2, varscan2
- ELN | c.240C>G p.G80= | Silent (SNP) | VAF 41/94 reads (44%) | called by muse, mutect2, varscan2
- FIG4 | c.1296A>C p.R432= | Silent (SNP) | VAF 19/128 reads (15%) | called by muse, mutect2, varscan2
- GADD45GIP1 | c.555G>A p.K185= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs746106552; called by muse, mutect2, varscan2
- GNA13 | c.732T>A p.L244= | Silent (SNP) | VAF 41/112 reads (37%) | called by muse, mutect2, varscan2
- HECTD4 | c.9795G>A p.V3265= | Silent (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- HELZ2 | c.6099G>A p.L2033= (on ENST00000467148 / NM_001037335.2; = p.L1464= on NM_033405.3) | Silent (SNP) | VAF 31/95 reads (33%) | called by muse, mutect2, varscan2
- HOXB3 | c.1248T>C p.P416= | Silent (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- IGFN1 | c.2454C>A p.V818= (on ENST00000295591 / NM_001367841.1; = p.V3275= on NM_001164586.2) | Silent (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- KIRREL3 | c.2271C>A p.S757= | Silent (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- LRRTM3 | c.1191G>A p.P397= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs1339003025, COSV63660750; called by muse, mutect2, varscan2
- MAP3K1 | c.3726A>G p.E1242= | Silent (SNP) | VAF 28/58 reads (48%) | called by muse, mutect2, varscan2
- MED24 | c.2415G>A p.P805= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs761413512; called by muse, mutect2, varscan2
- MRC1 | c.231G>T p.V77= | Silent (SNP) | VAF 28/140 reads (20%) | called by muse, mutect2, varscan2
- NAA10 | c.363C>G p.L121= | Silent (SNP) | VAF 26/54 reads (48%) | called by muse, mutect2, varscan2
- NCK2 | c.912G>A p.V304= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs375512251; called by muse, mutect2, varscan2
- NEXMIF | c.2208T>C p.A736= | Silent (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- OR12D2 | c.114T>A p.T38= | Silent (SNP) | VAF 42/58 reads (72%) | called by muse, mutect2, varscan2
- RTL5 | c.1305A>G p.E435= | Silent (SNP) | VAF 44/49 reads (90%) | called by muse, mutect2, varscan2
- SEMA3D | c.732T>A p.I244= | Silent (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- TAF4 | c.2190C>T p.V730= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as rs145691580; called by muse, mutect2, varscan2
- ZDHHC19 | c.189T>C p.V63= | Silent (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- ZNF438 | c.579G>A p.A193= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs568845590; called by muse, mutect2, varscan2
- ZNF449 | c.153C>G p.L51= | Silent (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- FAM74A3 | n.108A>G | RNA (SNP) | VAF 58/409 reads (14%) | called by muse, mutect2, varscan2
- LEKR1 | c.*1127T>A | 3'UTR (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- MIR221 | n.87C>G | RNA (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- MIR410 | n.26A>G | RNA (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
